Somatic mutation profile of tumor specimen TCGA-AK-3436-01A (aliquot TCGA-AK-3436-01A-02D-1386-10) from TCGA case TCGA-AK-3436, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 40.6 years (14,842 days).
Specimen TCGA-AK-3436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a00ed75b-aedc-4344-b5a4-39ccb0555f12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3436-10A (Blood Derived Normal), aliquot TCGA-AK-3436-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62b1b0bc-9292-4ef6-b765-e5a72f7c8192

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Nonsense Mutation 5, Splice Site 1, RNA 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.1085T>G p.V362G | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV66058637; called by muse, mutect2, varscan2
- ANGPT1 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52428996; called by muse, mutect2, varscan2
- AOX1 | c.3695G>T p.G1232V | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1242870736, COSV53494977; called by muse, mutect2, varscan2
- ASH1L | c.3443C>T p.T1148I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV64204919; called by muse, mutect2, varscan2
- ATXN2 | c.2825C>T p.A942V (on ENST00000550104; = p.A782V on NM_002973.4) | Missense Mutation (SNP) | VAF 121/616 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs1473391477, COSV66480900; called by muse, mutect2, varscan2
- CDH12 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 78/504 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV66385675; called by muse, mutect2, varscan2
- CTNNA3 | c.2654T>A p.V885D | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV65520709; called by muse, mutect2
- DNAAF3 | c.1205C>A p.A402E (on ENST00000524407 / NM_001256715.2; = p.A449E on NM_178837.4) | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV61274959; called by muse, mutect2, varscan2
- FAT3 | c.2869T>C p.W957R | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53070805; called by muse, mutect2
- FNIP2 | c.1583C>A p.S528Y | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52436130; called by muse, mutect2, varscan2
- FREM2 | c.8632A>G p.M2878V | Missense Mutation (SNP) | VAF 282/640 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV54826691; called by muse, mutect2, varscan2
- IDH1 | c.554A>C p.Q185P | Missense Mutation (SNP) | VAF 133/284 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.274); catalogued as COSV61615375; called by muse, mutect2, varscan2
- KANSL1L | c.2564+2C>T p.X855_splice | Splice Site (SNP) | VAF 95/453 reads (21%) | catalogued as COSV55989089; called by muse, mutect2, varscan2
- KRT6B | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 105/561 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV52881645; called by muse, mutect2, varscan2
- LRP1 | c.5996G>A p.R1999H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766366256, COSV54500784; called by muse, mutect2
- MYH1 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs745892725, COSV56843002, COSV56845614; called by muse, varscan2
- MYH1 | c.2053C>G p.P685A | Missense Mutation (SNP) | VAF 151/505 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs756916468, COSV56843009, COSV56854183; called by muse, mutect2, varscan2
- NAV3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV57058817; called by muse, mutect2, varscan2
- NET1 | c.523C>T p.R175W (on ENST00000355029 / NM_001047160.3; = p.R121W on NM_005863.5) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778125606, COSV61790657; called by muse, mutect2, varscan2
- OR7D4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV58071061; called by muse, mutect2, varscan2
- PAPSS1 | c.452T>G p.L151* | Nonsense Mutation (SNP) | VAF 79/272 reads (29%) | catalogued as COSV54487165; called by muse, mutect2, varscan2
- PATJ | c.1742A>G p.H581R | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57154634; called by muse, mutect2, varscan2
- PBRM1 | c.3028C>T p.R1010* | Nonsense Mutation (SNP) | VAF 127/223 reads (57%) | catalogued as COSV56258855; called by muse, mutect2, varscan2
- PGLYRP3 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as rs1476709643, COSV51948665; called by muse, mutect2, varscan2
- RBM11 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV68747905; called by muse, mutect2, varscan2
- RCC2 | c.1289G>A p.W430* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV64905169, COSV64906339; called by muse, mutect2, varscan2
- SLC9A2 | c.899C>G p.T300S | Missense Mutation (SNP) | VAF 191/432 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as COSV52128336; called by muse, mutect2, varscan2
- SPPL3 | c.613T>A p.F205I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62230946; called by muse, mutect2, varscan2
- STAMBP | c.1168T>C p.C390R | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59896727; called by muse, mutect2
- TMEM154 | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 148/627 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58589478; called by muse, mutect2, varscan2
- TRIM59 | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59086250; called by muse, varscan2
- UBE2D3 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 67/266 reads (25%) | catalogued as COSV57660223; called by muse, mutect2, varscan2
- URGCP | c.889G>C p.D297H (on ENST00000453200 / NM_001077663.3; = p.D288H on NM_017920.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56244675; called by muse, mutect2
- STK24 | c.678_679insT p.G227Wfs*31 | Frame Shift Ins (INS) | VAF 34/186 reads (18%) | called by pindel, varscan2
- B4GALT5 | c.180C>T p.I60= | Silent (SNP) | VAF 108/261 reads (41%) | catalogued as rs1347088909, COSV65492464, COSV65495634; called by muse, mutect2, varscan2
- CLRN1 | c.309C>A p.L103= (on ENST00000327047 / NM_174878.3; = p.L27= on NM_052995.2) | Silent (SNP) | VAF 101/325 reads (31%) | catalogued as COSV55804434; called by muse, mutect2, varscan2
- CUEDC2 | c.252A>T p.S84= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV56521980; called by muse, mutect2, varscan2
- FAH | c.321C>T p.F107= | Silent (SNP) | VAF 95/224 reads (42%) | catalogued as COSV55719861; called by muse, mutect2, varscan2
- PHTF2 | c.15C>G p.V5= | Silent (SNP) | VAF 80/465 reads (17%) | catalogued as COSV50323467; called by muse, mutect2, varscan2
- PPP1R3F | c.2010G>A p.G670= | Silent (SNP) | VAF 45/52 reads (87%) | catalogued as COSV50017624; called by muse, mutect2, varscan2
- SYT5 | c.771C>T p.T257= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as COSV62829579; called by muse, mutect2, varscan2
- TCF12 | c.354C>A p.S118= | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as COSV51003133; called by muse, mutect2, varscan2
- UBR3 | c.4500T>A p.I1500= | Silent (SNP) | VAF 78/361 reads (22%) | catalogued as COSV55843792; called by muse, mutect2, varscan2
- LINC02145 | n.484G>A | RNA (SNP) | VAF 10/64 reads (16%) | catalogued as rs1470159702; called by muse, mutect2
- MYH7 | c.4169+187C>A | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as COSV62515803; called by muse, mutect2, varscan2
